Somatic mutation profile of tumor specimen TCGA-DE-A69J-01A (aliquot TCGA-DE-A69J-01A-21D-A397-08) from TCGA case TCGA-DE-A69J, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 34.2 years (12,493 days).
Specimen TCGA-DE-A69J-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 54fae528-5bcd-4070-8bec-df6791e9f694.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DE-A69J-10A (Blood Derived Normal), aliquot TCGA-DE-A69J-10A-01D-A39A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/03cfb795-f579-4e2b-8345-c09c307ee748

The open-access MAF lists 5 somatic variants for this specimen: 5 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2, Nonsense Mutation 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 35/94 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- RBBP6 | c.658A>G p.I220V | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated, low confidence (0.16); PolyPhen possibly damaging (0.56); catalogued as rs1337166104, COSV100155121; called by muse, mutect2, varscan2
- TEX14 | c.2926C>T p.Q976* (on ENST00000240361 / NM_001201457.2; = p.Q970* on NM_031272.5) | Nonsense Mutation (SNP) | VAF 21/138 reads (15%) | catalogued as rs201354534, COSV99543884; called by muse, mutect2, varscan2
- ZNF543 | c.58C>T p.Q20* | Nonsense Mutation (SNP) | VAF 65/156 reads (42%) | catalogued as COSV100386977; called by muse, mutect2, varscan2
- CNGB3 | c.1359_1360insG p.Y454Vfs*8 | Frame Shift Ins (INS) | VAF 64/154 reads (42%) | called by mutect2, pindel*
